Somatic mutation profile of tumor specimen TCGA-WB-A81V-01A (aliquot TCGA-WB-A81V-01A-11D-A35I-08) from TCGA case TCGA-WB-A81V, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 57.8 years (21,106 days).
Specimen TCGA-WB-A81V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 810ba4e3-aa95-447d-a9a8-c0273b12e863.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81V-10A (Blood Derived Normal), aliquot TCGA-WB-A81V-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdf0cb66-2040-4157-868f-56a731b5c1e5

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 5, Frame Shift Ins 1, 5'UTR 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPIFA1 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs765939202, COSV62824970; called by muse, mutect2, varscan2
- MARCHF4 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774007024, COSV56106276, COSV99814928; called by muse, mutect2, varscan2
- ZNF564 | c.730A>G p.M244V | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.229); catalogued as rs1207358044; called by muse, mutect2, varscan2
- ANKRD28 | c.1021dup p.T341Nfs*12 | Frame Shift Ins (INS) | VAF 14/118 reads (12%) | called by mutect2, pindel, varscan2
- NF1 | c.4035_4050del p.F1346Sfs*27 (on ENST00000358273 / NM_001042492.3; = p.F1346Sfs*34 on NM_000267.3) | Frame Shift Del (DEL) | VAF 30/124 reads (24%) | called by mutect2, pindel, varscan2
- NF1 | c.5634T>A p.C1878* (on ENST00000358273 / NM_001042492.3; = p.C1857* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- PAPPA2 | c.3449A>G p.N1150S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- RYR1 | c.11559G>C p.E3853D | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- C10orf88 | c.1255C>T p.L419= | Silent (SNP) | VAF 4/67 reads (6%) | called by muse, mutect2
- CACNA1G | c.1038C>A p.A346= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs1360446470, COSV61722080; called by muse, mutect2, varscan2
- FOCAD | c.3360G>A p.S1120= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs149998482; called by muse, mutect2, varscan2
- KDM5B | c.4063C>T p.L1355= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- KLHL42 | c.504C>T p.L168= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV101179894; called by muse, mutect2, varscan2
- TGS1 | c.-1A>C | 5'UTR (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
